Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A72X, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A72X-01A (Primary Tumor).

ICD-O-3
Astrocytoma, grade III 9401/3
Site: Brain, Supratentorial NOS C71.0
QW 8/15/13

Case #

Patient: Age (years): Gender:

Clinical diagnosis: Brain tumor

Date of procurement:

Sample:

Gross description:

The material presented by dense-elastic pieces of grayish-brownish color with areas of sparse gray and white matter from left temporal lobe.

Microscopic description:

Received material is represented by brain tissue consistent with anaplastic astrocytoma, Grade III

Final diagnosis: Anaplastic astrocytoma, Grade III

Confidential

Duplicate/Synchronous Primary Noted		/

Source: NCI Genomic Data Commons file b86cf90c-bf12-433b-b715-2df5b05e1bff (TCGA-P5-A72X.6553F280-EF4A-4FAA-9FA8-38CC66A1AD40.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).